Somatic mutation profile of tumor specimen TCGA-F1-A72C-01A (aliquot TCGA-F1-A72C-01A-21D-A33T-08) from TCGA case TCGA-F1-A72C, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 68.7 years (25,104 days).
Specimen TCGA-F1-A72C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6932d2c0-5686-4fa1-a3c0-d57c54213370.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F1-A72C-10A (Blood Derived Normal), aliquot TCGA-F1-A72C-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41fb5184-4566-4572-9eae-ca8210413e09

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 30, Silent 15, Frame Shift Del 5, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ADCY8 | c.2295A>T p.K765N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV99654683; called by muse, varscan2
- ADGRD1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs750980141, COSV55441414; called by muse, mutect2
- ALS2 | c.2545A>G p.K849E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs746577109, COSV99970149; called by muse, mutect2, varscan2
- ARSJ | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100193184; called by muse, mutect2, varscan2
- C12orf40 | c.818del p.N273Mfs*12 | Frame Shift Del (DEL) | VAF 34/186 reads (18%) | catalogued as COSV104410248; called by mutect2, pindel, varscan2
- C16orf78 | c.574A>G p.S192G | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV100148005; called by muse, mutect2
- CACNA1C | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs377345545, COSV59696262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1I | c.4309T>A p.C1437S | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100361698, COSV60804954; called by muse, mutect2, varscan2
- CDH26 | c.1282A>C p.R428= | Splice Region (SNP) | VAF 55/383 reads (14%) | catalogued as COSV99722726; called by muse, mutect2, varscan2
- CHCHD3 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as rs771680335, COSV99366985; called by muse, mutect2, varscan2
- CUL7 | c.4951A>T p.T1651S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as COSV99539363; called by muse, mutect2
- DAB2IP | c.3458C>T p.T1153I (on ENST00000408936; = p.T1125I on NM_032552.3) | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV99406477; called by muse, mutect2, varscan2
- DYSF | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as rs761916273, COSV50281094; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRA1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.453); catalogued as rs778103654, COSV50109805; called by muse, mutect2, varscan2
- GHR | c.391A>G p.S131G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.132); catalogued as COSV100052212; called by muse, mutect2, varscan2
- GRK7 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.57); catalogued as rs766484380, COSV53824016; called by muse, mutect2, varscan2
- HYDIN | c.6595G>A p.G2199R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs755397309, COSV59251333, COSV59254377; called by muse, mutect2, varscan2
- JAKMIP1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs745353291, COSV51547338; called by muse, mutect2, varscan2
- MED15 | c.1615C>G p.L539V (on ENST00000263205 / NM_001003891.3; = p.L499V on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99488264; called by muse, mutect2, varscan2
- MTUS1 | c.1718A>G p.K573R | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100030153; called by muse, mutect2, varscan2
- OR5D13 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100687094; called by muse, mutect2
- OR9G4 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs139616824, COSV57248756; called by muse, mutect2, varscan2
- PARD3 | c.2399T>A p.I800N | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100402155; called by muse, mutect2, varscan2
- PLEC | c.4096C>T p.R1366W (on ENST00000322810 / NM_201380.4; = p.R1256W on NM_000445.5) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs781861123, COSV100519696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLK | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99606556; called by muse, mutect2
- PSIP1 | c.1224_1227del p.S409Rfs*2 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | catalogued as rs1408498843; called by mutect2, pindel, varscan2
- PSKH2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs149169337; called by muse, mutect2, varscan2
- RAG2 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100271535; called by muse, mutect2
- SGCE | c.857A>C p.Q286P (on ENST00000647096; = p.Q250P on NM_003919.3) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV99722981; called by muse, mutect2, varscan2
- SMAD4 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1064796102, COSV61685043, COSV61685722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPAG17 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100310782; called by muse, mutect2, varscan2
- VCL | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.105); catalogued as rs1271589037, COSV99281359; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV100008498; called by muse, mutect2, varscan2
- ARID2 | c.3560_3561del p.V1187Efs*53 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by pindel, varscan2
- MAMDC4 | c.2618_2619dup p.S874Pfs*3 (on ENST00000445819; = p.S795Pfs*3 on NM_206920.3) | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | called by mutect2, pindel, varscan2
- SHANK3 | c.4517del p.E1506Gfs*31 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- ZNF639 | c.1309_1312del p.E437Ifs*13 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- AARS1 | c.1041T>A p.A347= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99933843; called by muse, mutect2, varscan2
- BSN | c.1602C>A p.P534= | Silent (SNP) | VAF 14/273 reads (5%) | catalogued as COSV99610004; called by muse, mutect2
- CEP95 | c.27A>C p.V9= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99858346; called by muse, mutect2, varscan2
- JMJD1C | c.5100A>G p.K1700= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1416351734, COSV100550889; called by muse, mutect2, varscan2
- KRT76 | c.612G>A p.L204= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV100196565; called by muse, mutect2, varscan2
- LYPLAL1 | c.72G>T p.L24= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100859739; called by muse, mutect2, varscan2
- MEOX2 | c.906G>A p.A302= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs777058351, COSV56287124; called by muse, mutect2, varscan2
- MIP | c.414G>A p.T138= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs746222267, COSV57510051; called by muse, mutect2, varscan2
- MYBPC1 | c.2808A>G p.Q936= (on ENST00000550270 / NM_206820.2; = p.Q943= on NM_002465.4) | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs374499238, COSV100638311; called by muse, mutect2, varscan2
- RTN1 | c.1119C>T p.N373= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99957028; called by muse, mutect2
- RYR1 | c.2349G>A p.S783= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs753447100, COSV100617165; called by muse, mutect2, varscan2
- SLC35C2 | c.519G>C p.S173= | Silent (SNP) | VAF 28/192 reads (15%) | catalogued as COSV99709633; called by muse, mutect2, varscan2
- SORBS3 | c.1638C>G p.P546= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV99531272, COSV99531623; called by muse, mutect2, varscan2
- TPO | c.2727C>T p.A909= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs765076528, COSV100222332; called by muse, mutect2
- TSHZ3 | c.2709C>A p.L903= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99552961; called by muse, mutect2, varscan2
